Somatic mutation profile of tumor specimen HCM-CSHL-0089-C25-06A (aliquot HCM-CSHL-0089-C25-06A-11D-A78T-36) from HCMI case HCM-CSHL-0089-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 62.5 years (22,825 days).
Specimen HCM-CSHL-0089-C25-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a703f2e4-4412-4e1a-a9c9-efc000bdbfed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0089-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0089-C25-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef999162-6f8a-45a8-b19b-114394da3159

The open-access MAF lists 75 somatic variants for this specimen: 56 protein-altering or splice-affecting, 11 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 11, Frame Shift Ins 7, Frame Shift Del 5, Intron 4, RNA 2, 5'Flank 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 356/511 reads (70%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 125/280 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TG | c.7007G>A p.R2336Q | Missense Mutation (SNP) | VAF 207/805 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912650, CM063181, COSV55069861; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 236/392 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS2 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 207/513 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs763733632; called by muse, mutect2, varscan2
- ARID3A | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 58/232 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs781106095, COSV55046653; called by muse, mutect2, varscan2
- ARMC6 | c.1499C>T p.A500V (on ENST00000392336; = p.A475V on NM_033415.4) | Missense Mutation (SNP) | VAF 66/285 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.552); catalogued as rs1029406116; called by muse, mutect2, varscan2
- COL6A6 | c.2708G>A p.R903Q | Missense Mutation (SNP) | VAF 91/238 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1313232339, COSV62024644; called by muse, mutect2, varscan2
- CRY2 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs1277859534; called by muse, mutect2, varscan2
- CYP4F11 | c.572T>A p.M191K | Missense Mutation (SNP) | VAF 113/274 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1461992996; called by muse, mutect2, varscan2
- DLGAP2 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 132/382 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as rs1309261843; called by muse, mutect2, varscan2
- DUOX1 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 51/216 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144848407; called by muse, mutect2, varscan2
- EIF2AK1 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1384063838, COSV52240872; called by muse, mutect2, varscan2
- FAM216B | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.943); catalogued as COSV58270150; called by muse, mutect2, varscan2
- JAK3 | c.2519G>A p.R840H | Missense Mutation (SNP) | VAF 186/467 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as rs140837014; called by muse, varscan2
- KMT2D | c.13895del p.P4632Hfs*8 | Frame Shift Del (DEL) | VAF 69/178 reads (39%) | catalogued as CD114933; called by mutect2, pindel, varscan2
- MYOZ3 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 106/312 reads (34%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as rs766224195, COSV51739562; called by muse, mutect2, varscan2
- OGDHL | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 73/218 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs767864251, COSV65100729; called by muse, mutect2, varscan2
- OR13G1 | c.543G>T p.L181F | Missense Mutation (SNP) | VAF 36/264 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV62943607; called by muse, mutect2, varscan2
- PDZD2 | c.308dup p.K104Qfs*38 | Frame Shift Ins (INS) | VAF 74/479 reads (15%) | catalogued as rs750970663; called by mutect2, varscan2
- PSMA1 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.242); catalogued as rs770318291; called by muse, mutect2, varscan2
- PTPRD | c.5188C>T p.R1730W | Missense Mutation (SNP) | VAF 64/139 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775122610, COSV61982613; called by muse, mutect2, varscan2
- RUNX1T1 | c.1219G>A p.G407S (on ENST00000265814 / NM_001198628.1; = p.G380S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 228/649 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs202121288; called by muse, mutect2, varscan2
- SIDT2 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs777557219; called by muse, varscan2
- SMAD4 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 133/230 reads (58%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as rs1064796102, COSV61685043, COSV61685722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SULT4A1 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 140/325 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV50782227; called by muse, mutect2, varscan2
- THBS2 | c.1922C>T p.T641M | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); catalogued as rs1451706316, COSV64679569; called by muse, mutect2, varscan2
- TPO | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 63/301 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1210957618; ClinVar: uncertain significance; called by mutect2, varscan2
- TUBB8B | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 13/233 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as rs1438106680; called by muse, mutect2
- UNC5B | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 64/348 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs1157473537, COSV58975273, COSV58975519; called by muse, mutect2, varscan2
- VAV1 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 64/282 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as rs774426463; called by muse, mutect2, varscan2
- ZDBF2 | c.563C>A p.A188D | Missense Mutation (SNP) | VAF 91/196 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as COSV65622248; called by muse, mutect2, varscan2
- ZNF569 | c.389dup p.S132Ffs*7 | Frame Shift Ins (INS) | VAF 41/97 reads (42%) | catalogued as rs752923644; called by mutect2, pindel, varscan2
- ACSL5 | c.1871A>G p.Q624R (on ENST00000354273; = p.Q680R on NM_016234.3) | Missense Mutation (SNP) | VAF 68/180 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACVR2A | c.1309_1310del p.K437Efs*19 | Frame Shift Del (DEL) | VAF 64/167 reads (38%) | called by mutect2, pindel, varscan2
- ARMCX3 | c.654dup p.S219Ifs*17 | Frame Shift Ins (INS) | VAF 18/26 reads (69%) | called by mutect2, varscan2
- BTBD11 | c.979_988del p.A327Pfs*42 | Frame Shift Del (DEL) | VAF 50/210 reads (24%) | called by mutect2, pindel, varscan2
- CIC | c.3727_3728insT p.A1243Vfs*12 | Frame Shift Ins (INS) | VAF 56/245 reads (23%) | called by mutect2, pindel, varscan2
- CLNK | c.533dup p.E179* | Frame Shift Ins (INS) | VAF 35/131 reads (27%) | called by mutect2, pindel, varscan2
- CNBD1 | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- DEFB115 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 18/299 reads (6%) | SIFT tolerated (0.85); PolyPhen benign (0.432); called by muse, mutect2
- EPM2AIP1 | c.1055T>G p.F352C | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FANCG | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 121/493 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GNAT3 | c.107T>A p.L36Q | Missense Mutation (SNP) | VAF 95/259 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HAVCR1 | c.476C>A p.T159K | Missense Mutation (SNP) | VAF 248/608 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.063); called by mutect2, varscan2
- HOMER2 | c.442_445dup p.D149Gfs*3 (on ENST00000304231 / NM_199330.3; = p.D138Gfs*3 on NM_004839.4) | Frame Shift Ins (INS) | VAF 39/200 reads (20%) | called by mutect2, varscan2
- KLK6 | c.361C>A p.L121I | Missense Mutation (SNP) | VAF 118/294 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEXMIF | c.3808T>A p.S1270T | Missense Mutation (SNP) | VAF 150/203 reads (74%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCBP3 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); called by muse, varscan2
- PPP1R15B | c.566G>A p.S189N | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PRPF40A | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 179/398 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- PXMP2 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 83/405 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC41A3 | c.302del p.D101Afs*3 | Frame Shift Del (DEL) | VAF 22/94 reads (23%) | called by mutect2, pindel, varscan2
- TMEM94 | c.2605del p.M869Wfs*39 | Frame Shift Del (DEL) | VAF 60/163 reads (37%) | called by mutect2, pindel, varscan2
- ZFAND5 | c.557dup p.C186Wfs*4 | Frame Shift Ins (INS) | VAF 40/200 reads (20%) | called by mutect2, pindel, varscan2
- ZNF396 | c.338A>C p.Q113P | Missense Mutation (SNP) | VAF 105/247 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- CHD6 | c.6708C>T p.S2236= | Silent (SNP) | VAF 178/487 reads (37%) | catalogued as rs951814095; called by muse, mutect2, varscan2
- ELFN2 | c.57C>T p.A19= | Silent (SNP) | VAF 114/263 reads (43%) | catalogued as rs756407312; called by muse, mutect2, varscan2
- HUNK | c.570G>A p.E190= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV54227106; called by muse, mutect2, varscan2
- MATN4 | c.207C>T p.N69= | Silent (SNP) | VAF 56/151 reads (37%) | catalogued as COSV59212971; called by muse, mutect2, varscan2
- MUC4 | c.14625C>T p.N4875= (on ENST00000463781 / NM_018406.7; = p.N639= on NM_004532.6) | Silent (SNP) | VAF 88/246 reads (36%) | catalogued as rs1297779381; called by muse, mutect2
- NAT1 | c.279T>G p.V93= | Silent (SNP) | VAF 119/323 reads (37%) | called by muse, mutect2, varscan2
- OR2T6 | c.138C>T p.I46= | Silent (SNP) | VAF 45/87 reads (52%) | called by muse, mutect2, varscan2
- PPP2R1A | c.1182G>T p.V394= | Silent (SNP) | VAF 97/221 reads (44%) | called by muse, mutect2, varscan2
- RGS17 | c.573G>A p.L191= | Silent (SNP) | VAF 35/104 reads (34%) | called by muse, mutect2, varscan2
- SKOR1 | c.876C>T p.G292= | Silent (SNP) | VAF 31/120 reads (26%) | catalogued as rs746508508; called by muse, mutect2, varscan2
- ZBTB20 | c.420C>T p.I140= (on ENST00000474710 / NM_001164342.2; = p.I67= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 193/540 reads (36%) | catalogued as COSV61847669; called by muse, mutect2, varscan2
- ARHGEF19 | c.1138-94C>G | Intron (SNP) | VAF 22/78 reads (28%) | called by muse, mutect2
- ARHGEF4 | chr2:130916414 G>A | 5'Flank (SNP) | VAF 34/135 reads (25%) | called by muse, mutect2, varscan2
- CDH13 | c.-44C>T | 5'UTR (SNP) | VAF 58/409 reads (14%) | called by muse, mutect2, varscan2
- DENND2B | c.2283-29C>T | Intron (SNP) | VAF 132/744 reads (18%) | called by muse, mutect2, varscan2
- KCNU1 | c.2010-17035G>A | Intron (SNP) | VAF 107/299 reads (36%) | catalogued as rs769673898; called by muse, mutect2, varscan2
- MYLK | c.3652+49C>T | Intron (SNP) | VAF 94/276 reads (34%) | called by muse, mutect2, varscan2
- TUBB7P | n.37G>A | RNA (SNP) | VAF 27/239 reads (11%) | catalogued as rs782640561; called by muse, varscan2
- ZNF733P | n.628T>A | RNA (SNP) | VAF 26/262 reads (10%) | called by muse, varscan2
